Somatic mutation profile of tumor specimen 0E0WOI from CCDI case PBCVPK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0WOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bee59a17-3fad-44cd-90d0-2db9b41be884.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0WOW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0e95465-9ebb-4a9b-b784-a6c5436de943

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Frame Shift Ins 2, In Frame Ins 1, Nonsense Mutation 1, Silent 1, 3'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 153/757 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs990710819, COSV99961301; called by muse, mutect2, varscan2
- ADGRB2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 30/597 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1243425104; called by muse, mutect2
- CREBBP | c.1109del p.R370Qfs*19 | Frame Shift Del (DEL) | VAF 455/1022 reads (45%) | catalogued as COSV99272224; called by mutect2, varscan2
- EGFR | c.2320_2321insCCAACCCCCACG p.H773_V774insANPH | In Frame Ins (INS) | VAF 284/852 reads (33%) | catalogued as COSV51771114, COSV51821649; called by mutect2, varscan2
- KIZ | c.1283dup p.N428Kfs*11 | Frame Shift Ins (INS) | VAF 300/1220 reads (25%) | catalogued as rs755731853; called by mutect2, varscan2
- AKAP14 | c.202A>C p.M68L | Missense Mutation (SNP) | VAF 568/1259 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCOR | c.1912_1913insGA p.I638Rfs*32 | Frame Shift Ins (INS) | VAF 338/1010 reads (33%) | called by mutect2, varscan2
- C7 | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 457/1184 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.8698+2T>G p.X2900_splice | Splice Site (SNP) | VAF 390/884 reads (44%) | called by muse, mutect2, varscan2
- PRKDC | c.8851C>T p.Q2951* | Nonsense Mutation (SNP) | VAF 522/1322 reads (39%) | called by muse, mutect2, varscan2
- TET1 | c.5646G>A p.T1882= | Silent (SNP) | VAF 428/1074 reads (40%) | catalogued as COSV101018765, COSV65382167; called by muse, mutect2, varscan2
- ANKRD13A | c.945+64G>A | Intron (SNP) | VAF 148/329 reads (45%) | called by muse, mutect2, varscan2
- BCORL1 | c.4306-2882C>T | Intron (SNP) | VAF 343/890 reads (39%) | catalogued as COSV54390206; called by muse, mutect2, varscan2
- OR52K1 | c.*1A>G | 3'UTR (SNP) | VAF 242/543 reads (45%) | called by muse, mutect2, varscan2
